EXCEPTIONAL_RESPONDERS case ER-ADJ2 — Exceptional Responders (EXCEPTIONAL_RESPONDERS-ER)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Myomatous Neoplasms; Primary site: Uterus, NOS. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/125c92d3-0590-43d2-9119-ec4c4a15acb5

Demographics
Sex at birth: female; Race: white; Year of birth: 1948; Vital status: Alive.

Diagnoses (1)
1. Leiomyosarcoma, NOS: ICD-O-3 morphology code: 8890/3; Tissue or organ of origin: Uterus, NOS; Site of resection or biopsy: Uterus, NOS; Classification of tumor: primary; Age at diagnosis: 63.0 years (23,016 days); Year of diagnosis: 2011; AJCC pathologic stage: Stage IV; Days to last follow up: 1,781 days (4.9 years); Days to best overall response: 572 days (1.6 years); Best overall response: Complete Response.
   Treatment given: Therapeutic agents: Docetaxel + Gemcitabine Hydrochloride; Days to treatment start: 41 days; Days to treatment end: 292 days.

Follow-up (1 entry)
- Days to follow up: 1,781 days (4.9 years); Disease response: Stable Disease; Progression or recurrence: No; Days progression-free: 1,781 days (4.9 years).

Biospecimens (1 sample; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample ER-ADJ2-TTM1-A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: FFPE.
  Slide ER-ADJ2-TTM1-A-1-0-S1: Section location: Top; Percent tumor cells: 90; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 10; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
